Somatic mutation profile of tumor specimen TARGET-10-PAPIHH-09A (aliquot TARGET-10-PAPIHH-09A-01D) from TARGET case TARGET-10-PAPIHH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,743 days).
Specimen TARGET-10-PAPIHH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb3718db-32ed-4ebc-8a9b-e2b9d720be43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPIHH-10A (Blood Derived Normal), aliquot TARGET-10-PAPIHH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/440f395b-cdc2-4d6e-96c3-615fc10a3e7f

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 26/81 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CSMD1 | c.5290G>A p.V1764I (on ENST00000520002; = p.V1763I on NM_033225.6) | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs752235970, COSV59344777; called by muse, mutect2, varscan2
- DCLK1 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs758716913, COSV55173970; called by muse, mutect2, varscan2
- GATA4 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs180765750; called by muse, mutect2, varscan2
- MGAM2 | c.3484C>T p.R1162C | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763834845; called by muse, mutect2, varscan2
- PLXNB1 | c.4007C>T p.T1336M | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs773563319; called by muse, mutect2, varscan2
- SLC34A2 | c.688G>C p.V230L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs957622809; called by muse, mutect2, varscan2
- STK36 | c.2531G>A p.G844D | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV55329966; called by muse, mutect2, varscan2
- ZNF462 | c.2849C>T p.T950M | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs765428860, COSV99470992; called by muse, mutect2, varscan2
- ABAT | c.901_902insTCC p.D301delinsVH | In Frame Ins (INS) | VAF 12/27 reads (44%) | called by mutect2, pindel*, varscan2
- ABCB1 | c.3195G>A p.T1065= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs368096241; ClinVar: drug response; called by muse, mutect2, varscan2
- KCNJ4 | c.930C>T p.S310= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as rs767681232; called by muse, mutect2, varscan2
- PKHD1L1 | c.2403G>A p.T801= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs267601713, COSV65736382; called by muse, mutect2, varscan2
- GRIK1 | c.1794-784A>G | Intron (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
